Somatic mutation profile of tumor specimen 0DW42E from CCDI case PBCNPR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 6.5 years (2,361 days).
Specimen 0DW42E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 432aaf0a-d069-4833-b48b-94652dee52a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW41Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29bc0d48-04f3-49ad-8306-134543ad39b9

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC42EP4 | c.55del p.R19Efs*8 | Frame Shift Del (DEL) | VAF 88/263 reads (33%) | catalogued as COSV59962150, COSV59962845; called by mutect2, varscan2
- NRROS | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs781579121, COSV100145560; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1378C>G p.H460D | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- CNGB3 | c.174T>C p.T58= | Silent (SNP) | VAF 186/684 reads (27%) | called by muse, mutect2, varscan2
- KDM8 | c.1174C>T p.L392= | Silent (SNP) | VAF 118/374 reads (32%) | catalogued as rs1014678708, COSV53730022; called by muse, mutect2, varscan2
- TMEM272 | c.474G>A p.A158= | Silent (SNP) | VAF 111/299 reads (37%) | catalogued as rs141298705, COSV71749269; called by muse, mutect2, varscan2
- CYP4F3 | c.199-1776C>A | Intron (SNP) | VAF 31/145 reads (21%) | called by muse, varscan2
